Somatic mutation profile of tumor specimen BA2885D (aliquot aq-BA2885D) from BEATAML1.0 case 2139, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.2 years (29,673 days).
Specimen BA2885D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 519db8e9-0f26-48d8-a20b-389ac4126e95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3007D (Solid Tissue Normal), aliquot aq-BA3007D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e36eaa0d-349c-4fd6-b887-acc545833883

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- URGCP | c.2268G>T p.L756F (on ENST00000453200 / NM_001077663.3; = p.L747F on NM_017920.4) | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV56245669; called by muse, mutect2
- TNKS | c.506C>A p.A169E | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.034); called by muse, mutect2
- VPS28 | c.191G>T p.S64I | Missense Mutation (SNP) | VAF 3/60 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.157); called by muse, mutect2
- INTS1 | c.5214G>T p.L1738= | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- MARVELD1 | c.483C>A p.G161= | Silent (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- ZNF408 | c.1546C>A p.R516= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs754950117; called by muse, mutect2
